Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CS, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CS-01A (Primary Tumor).

[page 1 of 2]
Redacted al Pathology Report

DOB:
Physician:

Sex: F

Collected:
Received:

Accession:

Case type: Surgical Case

DIAGNOSIS

(A) RIGHT NECK LEVEL II LYMPH NODE:

One lymph node, no tumor present (0/1).

(B) RIGHT NECK LEVEL II, III, IV:

Three lymph nodes, no tumor present (0/3).

Pending sections.

(C) COMPLETION THYROIDECTOMY, RADICAL RESECTION OF TRACHEA, ESOPHAGEAL, PARTIAL LARYNGECTOMY:

PAPILLARY THYROID CARCINOMA EXTENDING INTO PERITHYROID SOFT TISSUE AND TRACHEA (4.0 CM).
Sixteen lymph nodes, no tumor present (0/16).

1CD-0-3
carcinoma, papillary thyroid 8260/3
Site: thyroid nos 73.9 lw 10/15/11

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) RIGHT NECK LEVEL II LYMPH NODE - A single lymph node measuring 2.0 x 1.0 x 0.8 cm. Serially sectioned and entirely submitted in A.

(B) RIGHT NECK, LEVELS II, III, AND IV - A 12.0 x 4.0 x 1.0 cm piece of fibroadipose tissue, unoriented. The specimen is serially sectioned and multiple lymph nodes are identified ranging in size from 0.5 to 1.0 cm in diameter. The lymph nodes are submitted in cassettes B1-B4 (multiple lymph nodes per cassette). NOTE: The surgeon was contacted about the orientation of the specimen. Levels of the specimen was not a issue.

(C) COMPLETION THYROIDECTOMY, RADICAL RESECTION OF TRACHEA, ESOPHAGEAL PARTIAL LARYNGECTOMY RESECTION - Thyroidectomy and partial laryngectomy specimen with overall measurements of 4.5 x 5.0 x 3.5 cm. Attached soft tissue and muscles are noted. The tumor is hemorrhagic, friable, light-tan to firm and measure approximately 3.0 x 2.0 x 4.0 cm. The tumor extends to the soft tissue but no involvement of the external margins of resection are noted. The tumor abuts and perhaps superficially invades the trachea anteriorly, but no involvement of the inner side of the tracheal surface is noted. The specimen is submitted under C1-C11, representative section of the tumor and the trachea and soft tissue from right to left. The remaining of the left soft tissue is examined and a total of 18 possible lymph nodes are identified. Representative sections as per section code.

SECTION CODE: C1-C11, representative section of the tumor and the trachea and soft tissue from right to left. The remaining of the left soft tissue is examined and a total of 18 possible lymph nodes are identified. Representative sections as per section code; C12-C14, four possible lymph node, each, from left soft tissue; C15, two possible lymph nodes, from left soft tissue; C16-C19, one possible lymph node, bisected, each, from left soft tissue; C20, two possible lymph nodes, from anterior soft tissue; C21, two possible lymph nodes from inferior soft tissue.

CLINICAL HISTORY

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,

DOB:
Physician:

Sex: F

Collected: (

Received:

Pathologist:

Accession:

9 Case type: Surgical Case

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Released by:

Surgical Pathology Report	Page 2 of 2
File under: Pathology	

Source: NCI Genomic Data Commons file 449bbf14-d37a-4242-b0ad-f29b046d5d91 (TCGA-EL-A3CS.E34678CC-5509-47BE-8594-8F77A8243111.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).